Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2A6, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2A6-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

C-plex to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Metastatic melanoma right groin. Right groin contents. Iliac and obturator nodes.
Histopathology.

FROZEN SECTION REPORT

Fresh tissue was taken (from largest involved node) for tumour banking.
(Registrar/ Pathologist:

MACROSCOPIC DESCRIPTION

(Dr

Two specimens were received.

1. "CONTENTS OF RIGHT GROIN DISSECTION STAPLES UPPER". A piece of fibrofatty tissue measuring 155 x 75 x 35mm. There is an overlying ellipse of skin 140 x 25mm. Staple marks upper as per specimen label. Near the direction of the staple there is a large involved lymph node with a homogenous tan cut surface measuring 35 x 25 x 25mm. Almost the entire lymph node is replaced by metastatic tumour.

- A. Representative section of the involved lymph node near the staple.
- B. An additional lymph node near the staple.
- C-D. One lymph node bisected.
- E-F. One bisected lymph node.
- G-H. One bisected lymph node in each block.
- J. One bisected lymph node.
- K. Three lymph nodes.
- L. Representative sections of skin.

2. "RIGHT ILIAC AND OBTURATOR NODES". Multiple fragments of tan tissue 95 x 60 x 30mm.

- A-F. One fatty lymph node in six parts.
- G-N. One fatty lymph node in seven parts.
- P-R. One lymph node trisected.
- S. One bisected lymph node.
- T. One bisected lymph node.
- U. One bisected lymph node.
- V. Three lymph nodes.
- W. Four lymph nodes.
- X. Four lymph nodes.
- Y. Five lymph nodes.

for 4/21/11

A Unit on:

Piv

Page 1 of 2

This fax was received by

more information.

[page 2 of 2]
Requested by

MRN/N:

Local

Accession:

HISTOPATHOLOGY REPORT**MICROSCOPIC REPORT****1. "CONTENTS OF RIGHT GROIN DISSECTION STAPLES UPPER".**

There is metastatic melanoma involving 1 of 10 lymph nodes. The melanoma extensively replaces the node and consists of sheets of large epithelioid cells with eccentric nuclei, prominent nucleoli and frequent intranuclear pseudoinclusions. No extranodal spread is seen.

Immunohistochemical stains show the tumour cells are strongly positive for S100, melanA and HMB-45, consistent with melanoma. Stains for CD45 and cytokeratin are negative in the tumour cells. The uninvolved nodes and skin show no significant abnormalities.

2. "RIGHT ILLIAC AND OBTURATOR NODES".

There are 22 lymph nodes showing no evidence of malignancy.

SUMMARY

1. Lymph nodes, right groin dissection: METASTATIC MELANOMA (1/10).

2. Lymph nodes, right iliac and obturator: No evidence of malignancy (0/22).

REPORTED BY: A/Prof.

A Unit c

Print

Page 4 of 4

This fax was received by:

ver. For more information,

Source: NCI Genomic Data Commons file a9d78aca-fcf2-48d8-86e9-e981cbbef641 (TCGA-EE-A2A6.8B6460D2-6763-420C-9912-E17F429EE9F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).